Gene-level copy-number profile of tumor specimen HCM-SANG-0780-C25-01A-01D-A80T-32 from HCMI case HCM-SANG-0780-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2.
Specimen HCM-SANG-0780-C25-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a4683d79-64b6-452e-b797-ae20a1e2f5c5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0780-C25-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/5d4d021c-0136-4bd1-a405-444fd8ac6b93

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 135; copy number 1: 17,174; copy number 2: 34,223; copy number 3: 3,520; copy number 4: 3,858.

Homozygous deletions (total copy number 0; autosomes only): 134 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:84,544,304–84,544,519, 1 gene: RPL3P13.
- chr15:19,964,666–22,282,872, 122 genes (broad region; genes not listed).
- chr17:32,408,013–32,412,420, 3 genes: AC005899.6, AC005899.7, AC005899.5.
- chr17:32,430,967–32,432,841, 1 gene (within-gene range 0–2): AC005899.1.
- chr17:75,898,645–76,005,999, 7 genes (within-gene range 0–2): AC087289.3, FBF1, ACOX1, AC087289.4, TEN1-CDK3, TEN1, CDK3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 14,319. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
